Gene-level copy-number profile of tumor specimen TCGA-VS-A94W-01A from TCGA case TCGA-VS-A94W, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 39.4 years (14,399 days).
Specimen TCGA-VS-A94W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.f2642857-0764-41e4-8261-719b7c227b36.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VS-A94W-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e97444c8-b53d-4299-8cc2-b06dceeb3eae

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 19; copy number 1: 3,042; copy number 2: 46,290; copy number 3: 6,106; copy number 4: 2,421; copy number 7: 1,802; copy number 25: 89; copy number 29: 40; copy number 32: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VS-A94W-01A-12D-A37M-01): tumor purity 0.56, ploidy 2.18, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 19 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:102,777,449–103,241,972, 19 genes (within-gene range 0–2): TRAF3, RNU6-1316P, AMN, CDC42BPB, AL117209.1, RPL13P6, LBHD2, AL161669.1, EXOC3L4, AL161669.4, LINC00677, TNFAIP2, NDUFB4P11, RPL21P12, GCSHP2, LINC00605, AL161669.2, AL161669.3, RPL21P13.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,940 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:91,356,755–198,222,513, 1,802 genes, copy number 7 (broad region; genes not listed).
- chr9:3,218,297–14,398,983, 138 genes, copy number 25–32 (within-gene range 2–32) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,042. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
